Gene-level copy-number profile of tumor specimen C3L-02661-01 from CPTAC case C3L-02661, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 59.2 years (21,632 days).
Specimen C3L-02661-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8157a984-4b36-4d75-9961-2662b4e474a5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02661-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/9e241cad-f54b-4994-be9e-404882f21bec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 13,391; copy number 2: 35,960; copy number 3: 9,495; copy number 4: 2; copy number 5: 50; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 51 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:73,209,083–75,593,145, 50 genes, copy number 5: KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7, AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2, AL356473.1, COL12A1, COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P.
- chr16:32,600,299–32,615,639, 1 gene, copy number 7: AC137800.1.

Autosomal genes at a single copy (total copy number 1): 10,549. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
